Somatic mutation profile of tumor specimen MMRF_1831_1_BM_CD138pos (aliquot MMRF_1831_1_BM_CD138pos_T1_KBS5U_K11327) from MMRF case MMRF_1831, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 69.4 years (25,346 days).
Specimen MMRF_1831_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0c8c343b-4111-4e7c-bbc6-e2ba69910b08.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1831_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1831_1_PB_Whole_C2_KBS5U_K11328; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e0bfa41b-d776-4687-8726-0854ee447d6b

The open-access MAF lists 202 somatic variants for this specimen: 76 protein-altering or splice-affecting, 33 silent, 93 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 63, 3'UTR 48, Silent 33, Intron 27, 5'UTR 10, Nonsense Mutation 4, 3'Flank 4, Frame Shift Ins 3, RNA 3, Frame Shift Del 3, 5'Flank 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.396G>C p.K132N | Missense Mutation (SNP) | VAF 49/54 reads (91%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs866775781, COSV52688381, COSV52705927, COSV52891203, COSV53339296; ClinVar: conflicting interpretations of pathogenicity / likely pathogenic; called by muse, mutect2, varscan2
- ACTB | c.152A>G p.D51G | Missense Mutation (SNP) | VAF 70/149 reads (47%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.948); catalogued as rs746568210; called by muse, mutect2, varscan2
- ADGRF1 | c.1843A>T p.K615* | Nonsense Mutation (SNP) | VAF 89/196 reads (45%) | catalogued as rs1443267963; called by muse, mutect2, varscan2
- BCL7A | c.2T>C p.M1? | Translation Start Site (SNP) | VAF 8/30 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.775); catalogued as COSV55849318; called by muse, mutect2
- CACNA1A | c.2545G>A p.V849M | Missense Mutation (SNP) | VAF 42/210 reads (20%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as rs1168020406, COSV64202185; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CAPN14 | c.1955G>A p.R652H | Missense Mutation (SNP) | VAF 40/79 reads (51%) | SIFT tolerated (0.06); PolyPhen benign (0.006); catalogued as rs375553136; called by muse, mutect2, varscan2
- CCAR2 | c.1514del p.L505Qfs*12 | Frame Shift Del (DEL) | VAF 94/248 reads (38%) | catalogued as rs1280225975, COSV52386853; called by mutect2, pindel, varscan2
- CFAP47 | c.1658A>C p.K553T | Missense Mutation (SNP) | VAF 83/85 reads (98%) | SIFT tolerated (0.41); PolyPhen benign (0.105); catalogued as rs749911825; called by muse, mutect2, varscan2
- CGREF1 | c.511C>A p.L171I | Missense Mutation (SNP) | VAF 12/156 reads (8%) | SIFT tolerated (0.31); PolyPhen benign (0.058); catalogued as COSV53148864; called by muse, mutect2
- CHGB | c.1723C>A p.P575T | Missense Mutation (SNP) | VAF 38/77 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.961); catalogued as COSV100972957; called by muse, mutect2, varscan2
- CRISP2 | c.723A>C p.K241N | Missense Mutation (SNP) | VAF 99/182 reads (54%) | SIFT deleterious (0); PolyPhen benign (0.432); catalogued as rs577428520; called by muse, mutect2, varscan2
- CROCC2 | c.790C>T p.R264C | Missense Mutation (SNP) | VAF 39/94 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs1189795062; called by muse, mutect2, varscan2
- EZH2 | c.2158G>A p.E720K (on ENST00000460911 / NM_001203247.2; = p.E725K on NM_004456.5) | Missense Mutation (SNP) | VAF 57/144 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs747933788, COSV57457547; called by muse, mutect2, varscan2
- FST | c.333_335del p.K111del | In Frame Del (DEL) | VAF 16/50 reads (32%) | catalogued as rs772816396; called by pindel, varscan2
- GRIK2 | c.1060C>T p.R354C | Missense Mutation (SNP) | VAF 56/130 reads (43%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.925); catalogued as rs755777802, COSV59784426; called by muse, mutect2, varscan2
- H1-5 | c.410C>T p.A137V | Missense Mutation (SNP) | VAF 16/172 reads (9%) | SIFT tolerated (0.08); PolyPhen benign (0.021); catalogued as rs768102848, COSV58899555; called by muse, mutect2
- IGHV2-70 | c.64A>G p.T22A | Missense Mutation (SNP) | VAF 26/64 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.152); catalogued as rs755395069; called by muse, varscan2
- IGLL5 | c.82C>G p.L28V | Missense Mutation (SNP) | VAF 25/55 reads (45%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.08); catalogued as rs148489860, COSV73248966, COSV73250113; called by muse, mutect2, varscan2
- IGLV3-1 | c.305C>T p.A102V | Missense Mutation (SNP) | VAF 42/101 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.873); catalogued as rs145774047; called by muse, varscan2
- IQCH | c.2187G>C p.W729C | Missense Mutation (SNP) | VAF 33/54 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1209637795; called by muse, mutect2, varscan2
- LRRC25 | c.640G>A p.G214S | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT tolerated (0.75); PolyPhen benign (0.001); catalogued as rs1181929782, COSV59115460; called by muse, mutect2, varscan2
- MBNL1 | c.907C>G p.L303V (on ENST00000282486 / NM_207293.2; = p.L285V on NM_021038.5 and 10 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 12/186 reads (6%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.977); catalogued as COSV56832995; called by muse, mutect2
- RPGRIP1L | c.3094G>A p.E1032K | Missense Mutation (SNP) | VAF 46/149 reads (31%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.555); catalogued as COSV100046436, COSV50913887; called by muse, mutect2, varscan2
- RUFY4 | c.581dup p.N194Kfs*16 | Frame Shift Ins (INS) | VAF 27/90 reads (30%) | catalogued as rs1212549134; called by mutect2, pindel, varscan2
- SPAM1 | c.384G>T p.K128N | Missense Mutation (SNP) | VAF 12/148 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.784); catalogued as COSV56146483; called by muse, mutect2
- TENM4 | c.5306G>A p.R1769Q | Missense Mutation (SNP) | VAF 39/171 reads (23%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.978); catalogued as rs761269282, COSV53622642; called by muse, mutect2, varscan2
- TGFBI | c.1502dup p.M502Nfs*15 | Frame Shift Ins (INS) | VAF 52/70 reads (74%) | catalogued as rs771515402; called by mutect2, varscan2
- TNXB | c.6205G>A p.V2069M (on ENST00000647633; = p.V1822M on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 32/80 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); catalogued as rs533134249; called by muse, mutect2, varscan2
- TSHZ2 | c.2702C>T p.A901V | Missense Mutation (SNP) | VAF 14/136 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV61588819; called by muse, mutect2
- URI1 | c.1600A>G p.K534E | Missense Mutation (SNP) | VAF 54/212 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.058); catalogued as rs1293717299; called by muse, mutect2, varscan2
- ACSM4 | c.1693G>A p.G565R | Missense Mutation (SNP) | VAF 54/150 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ATP8B3 | c.3514del p.T1172Rfs*12 | Frame Shift Del (DEL) | VAF 24/95 reads (25%) | called by mutect2, pindel, varscan2
- BMP5 | c.1052A>G p.Q351R | Missense Mutation (SNP) | VAF 49/109 reads (45%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.822); called by muse, mutect2, varscan2
- CDK5RAP2 | c.5417C>T p.P1806L | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CENPE | c.1081G>A p.E361K | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- CLPTM1 | c.1869dup p.T624Hfs*98 | Frame Shift Ins (INS) | VAF 25/137 reads (18%) | called by mutect2, pindel, varscan2
- COL5A1 | c.2036G>T p.G679V | Missense Mutation (SNP) | VAF 21/141 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); called by muse, mutect2, varscan2
- CYLD | c.1555A>T p.R519* | Nonsense Mutation (SNP) | VAF 3/15 reads (20%) | called by muse, mutect2
- CYLD | c.2842C>T p.Q948* | Nonsense Mutation (SNP) | VAF 3/10 reads (30%) | called by muse, mutect2, varscan2
- DDX58 | c.597T>G p.D199E | Missense Mutation (SNP) | VAF 115/176 reads (65%) | SIFT tolerated (0.61); PolyPhen benign (0); called by muse, mutect2, varscan2
- DLG1 | c.824_825del p.C275Yfs*6 | Frame Shift Del (DEL) | VAF 31/98 reads (32%) | called by mutect2, pindel, varscan2
- DYNC1H1 | c.7090T>A p.F2364I | Missense Mutation (SNP) | VAF 52/124 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- EHD3 | c.812T>C p.F271S | Missense Mutation (SNP) | VAF 84/186 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); called by muse, mutect2, varscan2
- EMC9 | c.242A>T p.Y81F | Missense Mutation (SNP) | VAF 59/158 reads (37%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- FAT4 | c.12541G>T p.D4181Y | Missense Mutation (SNP) | VAF 37/83 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- FCGBP | c.1712A>C p.Y571S | Missense Mutation (SNP) | VAF 32/63 reads (51%) | SIFT tolerated (0.13); PolyPhen benign (0.138); called by muse, mutect2, varscan2
- GOLM2 | c.1084G>C p.D362H | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GRIA1 | c.2549T>A p.I850N | Missense Mutation (SNP) | VAF 25/122 reads (20%) | SIFT tolerated (0.12); PolyPhen benign (0.392); called by muse, mutect2, varscan2
- H1-3 | c.464C>G p.T155S | Missense Mutation (SNP) | VAF 31/71 reads (44%) | SIFT tolerated (0.22); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- HLA-A | c.202A>G p.R68G | Missense Mutation (SNP) | VAF 3/54 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.152); called by muse, mutect2
- IGF2BP3 | c.775T>A p.S259T | Missense Mutation (SNP) | VAF 22/77 reads (29%) | SIFT tolerated (0.48); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- IGHV1-69D | c.234C>G p.N78K | Missense Mutation (SNP) | VAF 41/52 reads (79%) | SIFT tolerated (0.66); PolyPhen benign (0.003); called by muse, varscan2
- IGKV1-6 | c.91T>C p.S31P | Missense Mutation (SNP) | VAF 8/68 reads (12%) | SIFT tolerated (0.05); PolyPhen benign (0.076); called by mutect2, varscan2
- MEGF8 | c.1517G>A p.R506Q | Missense Mutation (SNP) | VAF 31/64 reads (48%) | SIFT tolerated (0.14); PolyPhen benign (0.315); called by muse, mutect2, varscan2
- MPDZ | c.5540G>A p.S1847N (on ENST00000319217 / NM_001330637.2; = p.S1818N on NM_003829.5) | Missense Mutation (SNP) | VAF 33/126 reads (26%) | SIFT tolerated (0.43); PolyPhen benign (0); called by muse, mutect2, varscan2
- MPP7 | c.350A>T p.K117M | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- MYH6 | c.2419G>A p.V807M | Missense Mutation (SNP) | VAF 37/74 reads (50%) | SIFT tolerated (0.61); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- NR1H2 | c.770C>T p.P257L | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT tolerated (0.18); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- NTM | c.441T>G p.I147M | Missense Mutation (SNP) | VAF 183/325 reads (56%) | SIFT deleterious (0); PolyPhen possibly damaging (0.82); called by muse, mutect2, varscan2
- PLEKHM2 | c.1266C>A p.D422E | Missense Mutation (SNP) | VAF 17/87 reads (20%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.223); called by muse, mutect2, varscan2
- PLXNA2 | c.3461T>C p.L1154S | Missense Mutation (SNP) | VAF 6/94 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); called by muse, mutect2
- PPFIA3 | c.266T>A p.L89Q | Missense Mutation (SNP) | VAF 52/125 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PTPN14 | c.1772G>C p.S591T | Missense Mutation (SNP) | VAF 13/109 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.475); called by muse, mutect2, varscan2
- RBM5 | c.313C>T p.L105F | Missense Mutation (SNP) | VAF 9/140 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- RERE | c.2102C>A p.P701H | Missense Mutation (SNP) | VAF 65/151 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- SEC24C | c.1054C>T p.Q352* | Nonsense Mutation (SNP) | VAF 14/128 reads (11%) | called by muse, mutect2
- SLC12A9 | c.1713C>T p.D571= | Splice Region (SNP) | VAF 7/30 reads (23%) | called by muse, mutect2, varscan2
- SPIN1 | c.672T>A p.D224E | Missense Mutation (SNP) | VAF 44/184 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- TRMT112 | c.124G>A p.V42M | Missense Mutation (SNP) | VAF 58/425 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.537); called by muse, mutect2, varscan2
- UNC5D | c.2540G>C p.G847A | Missense Mutation (SNP) | VAF 65/151 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- URB1 | c.3440A>C p.E1147A | Missense Mutation (SNP) | VAF 14/231 reads (6%) | SIFT tolerated (0.22); PolyPhen benign (0.039); called by muse, mutect2
- WDR19 | c.133G>T p.G45C | Missense Mutation (SNP) | VAF 24/49 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- WWC3 | c.2813T>C p.F938S | Missense Mutation (SNP) | VAF 53/58 reads (91%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZNF257 | c.1555G>A p.E519K | Missense Mutation (SNP) | VAF 31/176 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- ZNF423 | c.3185C>A p.S1062Y (on ENST00000563137 / NM_001379286.1; = p.S1054Y on NM_015069.4) | Missense Mutation (SNP) | VAF 49/56 reads (88%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.923); called by muse, mutect2, varscan2
- ZNF804B | c.2527C>A p.P843T | Missense Mutation (SNP) | VAF 50/140 reads (36%) | SIFT tolerated (0.47); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ACTA1 | c.144T>C p.G48= | Silent (SNP) | VAF 68/136 reads (50%) | catalogued as rs1265100143, COSV64204209; called by muse, mutect2, varscan2
- AP5B1 | c.1185C>T p.P395= | Silent (SNP) | VAF 20/104 reads (19%) | called by muse, mutect2, varscan2
- ARHGEF1 | c.990C>T p.S330= | Silent (SNP) | VAF 14/81 reads (17%) | catalogued as COSV100528915; called by muse, mutect2, varscan2
- C1orf167 | c.2517C>G p.P839= | Silent (SNP) | VAF 49/68 reads (72%) | catalogued as COSV57174925; called by muse, mutect2, varscan2
- CD33 | c.522C>T p.P174= | Silent (SNP) | VAF 61/246 reads (25%) | catalogued as rs1189704947, COSV99220738; called by muse, mutect2, varscan2
- CDH7 | c.372G>A p.A124= | Silent (SNP) | VAF 27/67 reads (40%) | catalogued as rs375091808; called by muse, mutect2, varscan2
- CHST12 | c.208C>T p.L70= | Silent (SNP) | VAF 38/126 reads (30%) | called by muse, mutect2, varscan2
- CXCR6 | c.309G>A p.K103= | Silent (SNP) | VAF 25/89 reads (28%) | called by muse, mutect2, varscan2
- EML2 | c.132C>T p.C44= | Silent (SNP) | VAF 13/60 reads (22%) | called by muse, mutect2, varscan2
- ERP44 | c.45C>A p.S15= | Silent (SNP) | VAF 57/268 reads (21%) | called by muse, mutect2, varscan2
- EXPH5 | c.2352G>A p.P784= | Silent (SNP) | VAF 51/230 reads (22%) | catalogued as rs367982814; called by muse, mutect2, varscan2
- FIBIN | c.399G>A p.S133= | Silent (SNP) | VAF 42/276 reads (15%) | catalogued as rs1245206562, COSV59413192; called by muse, mutect2, varscan2
- GRAMD1B | c.1746G>A p.P582= | Silent (SNP) | VAF 9/92 reads (10%) | catalogued as rs781626323; called by muse, mutect2, varscan2
- IGLL5 | c.195C>T p.S65= | Silent (SNP) | VAF 9/19 reads (47%) | catalogued as rs151173231, COSV104440338, COSV73251128; called by muse, varscan2
- KBTBD11 | c.1557G>A p.P519= | Silent (SNP) | VAF 12/24 reads (50%) | catalogued as rs772567717; called by muse, mutect2
- KCNQ2 | c.543G>A p.A181= | Silent (SNP) | VAF 25/81 reads (31%) | catalogued as rs1447421194; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- KLHL24 | c.1209T>A p.A403= | Silent (SNP) | VAF 24/70 reads (34%) | called by muse, mutect2, varscan2
- KY | c.141C>T p.F47= | Silent (SNP) | VAF 61/168 reads (36%) | called by muse, mutect2, varscan2
- MAF | c.417C>G p.A139= | Silent (SNP) | VAF 9/11 reads (82%) | called by muse, mutect2, varscan2
- MAGEE1 | c.564G>A p.V188= | Silent (SNP) | VAF 160/167 reads (96%) | called by muse, mutect2, varscan2
- MAGEL2 | c.2841G>A p.E947= | Silent (SNP) | VAF 67/173 reads (39%) | catalogued as rs941843764; called by muse, mutect2, varscan2
- MRPL41 | c.285C>T p.A95= | Silent (SNP) | VAF 64/433 reads (15%) | catalogued as rs1308659383; called by muse, mutect2, varscan2
- NACC1 | c.348C>T p.G116= | Silent (SNP) | VAF 73/167 reads (44%) | called by muse, mutect2, varscan2
- NETO1 | c.681T>C p.N227= | Silent (SNP) | VAF 78/160 reads (49%) | called by muse, mutect2, varscan2
- OLIG2 | c.531C>T p.Y177= | Silent (SNP) | VAF 10/21 reads (48%) | catalogued as rs1485070775, COSV100324332; called by muse, mutect2, varscan2
- SCAF11 | c.1725A>G p.V575= | Silent (SNP) | VAF 6/70 reads (9%) | called by muse, mutect2
- SH3BGRL | c.159A>G p.V53= | Silent (SNP) | VAF 165/171 reads (96%) | catalogued as COSV100943396; called by muse, mutect2, varscan2
- SLC13A2 | c.513C>A p.G171= | Silent (SNP) | VAF 8/73 reads (11%) | called by muse, mutect2, varscan2
- SPON1 | c.1722C>T p.C574= | Silent (SNP) | VAF 48/156 reads (31%) | catalogued as rs1203820672; called by muse, mutect2, varscan2
- SRCIN1 | c.288G>A p.L96= | Silent (SNP) | VAF 24/61 reads (39%) | catalogued as rs1234814616; called by muse, mutect2, varscan2
- TNC | c.996C>T p.C332= | Silent (SNP) | VAF 36/191 reads (19%) | catalogued as rs573086700, COSV60787751; called by muse, mutect2, varscan2
- TP53BP2 | c.201A>G p.R67= | Silent (SNP) | VAF 4/73 reads (5%) | called by muse, mutect2
- TRPC4AP | c.1032G>A p.E344= | Silent (SNP) | VAF 19/65 reads (29%) | catalogued as COSV52681784; called by muse, mutect2, varscan2
- ACVR2B | c.-3A>T | 5'UTR (SNP) | VAF 8/15 reads (53%) | called by muse, mutect2, varscan2
- ALG10 | c.-62C>T | 5'UTR (SNP) | VAF 35/72 reads (49%) | called by muse, mutect2, varscan2
- APLN | c.*1218G>A | 3'UTR (SNP) | VAF 32/65 reads (49%) | catalogued as rs750640539; called by muse, mutect2, varscan2
- APTX | c.133+58A>G | Intron (SNP) | VAF 22/109 reads (20%) | called by muse, mutect2, varscan2
- ARHGEF4 | c.-321C>A | 5'UTR (SNP) | VAF 75/203 reads (37%) | called by muse, mutect2, varscan2
- ARL14 | c.*316A>C | 3'UTR (SNP) | VAF 31/81 reads (38%) | called by muse, mutect2, varscan2
- ATOH8 | c.*527T>C | 3'UTR (SNP) | VAF 16/48 reads (33%) | called by muse, mutect2, varscan2
- ATP11C | c.-1010A>T | 5'UTR (SNP) | VAF 42/47 reads (89%) | called by muse, mutect2, varscan2
- ATRX | c.*1025C>T | 3'UTR (SNP) | VAF 24/66 reads (36%) | called by muse, mutect2, varscan2
- C16orf86 | c.*121G>C | 3'UTR (SNP) | VAF 6/29 reads (21%) | catalogued as rs1030702964; called by muse, mutect2
- C5orf38 | c.*3C>T | 3'UTR (SNP) | VAF 17/143 reads (12%) | called by muse, mutect2, varscan2
- CACNA1E | c.*3309C>T | 3'UTR (SNP) | VAF 9/91 reads (10%) | catalogued as rs371539286; called by muse, mutect2, varscan2
- CACNG8 | c.*2285C>A | 3'UTR (SNP) | VAF 16/102 reads (16%) | called by muse, mutect2, varscan2
- CARD9 | c.1078-32C>T | Intron (SNP) | VAF 34/123 reads (28%) | called by muse, mutect2, varscan2
- CCDC85C | c.*1490C>T | 3'UTR (SNP) | VAF 42/94 reads (45%) | catalogued as rs371438848; called by muse, mutect2
- CCM2 | c.31-10558T>A | Intron (SNP) | VAF 156/313 reads (50%) | called by muse, mutect2, varscan2
- CELF2 | c.1075+3337G>A | Intron (SNP) | VAF 13/107 reads (12%) | called by muse, mutect2, varscan2
- CGAS | c.*1044G>A | 3'UTR (SNP) | VAF 7/14 reads (50%) | called by muse, mutect2, varscan2
- CLIP1 | c.*370T>G | 3'UTR (SNP) | VAF 6/92 reads (7%) | called by muse, mutect2
- CNTN6 | c.-233G>T | 5'UTR (SNP) | VAF 4/54 reads (7%) | called by muse, mutect2
- CPNE4 | c.*1204G>A | 3'UTR (SNP) | VAF 18/93 reads (19%) | called by muse, mutect2, varscan2
- CYP4F3 | c.918+70T>C | Intron (SNP) | VAF 30/163 reads (18%) | called by muse, mutect2, varscan2
- CYP4F8 | c.526-96G>A | Intron (SNP) | VAF 7/33 reads (21%) | called by muse, mutect2, varscan2
- DUS1L | c.940-15C>T | Intron (SNP) | VAF 30/102 reads (29%) | called by muse, varscan2
- EIF1AD | c.-87-37C>T | Intron (SNP) | VAF 5/54 reads (9%) | catalogued as rs1451215025; called by muse, mutect2
- ESRRG | c.*2299G>T | 3'UTR (SNP) | VAF 86/92 reads (93%) | called by muse, varscan2
- EXT1 | c.*1014del | 3'UTR (DEL) | VAF 28/80 reads (35%) | called by mutect2, pindel, varscan2
- EXT1 | c.*717del | 3'UTR (DEL) | VAF 25/66 reads (38%) | called by mutect2, pindel, varscan2
- EYS | c.1766+4915A>C | Intron (SNP) | VAF 6/25 reads (24%) | called by muse, mutect2, varscan2
- FCRL2 | c.*16G>A | 3'UTR (SNP) | VAF 17/188 reads (9%) | called by muse, mutect2
- FMNL3 | c.-10C>G | 5'UTR (SNP) | VAF 32/76 reads (42%) | called by mutect2, varscan2
- FOXN2 | c.*3492C>T | 3'UTR (SNP) | VAF 16/29 reads (55%) | called by muse, mutect2, varscan2
- GCFC2 | c.1226+27G>A | Intron (SNP) | VAF 10/21 reads (48%) | called by muse, varscan2
- GDNF | c.*540del | 3'UTR (DEL) | VAF 28/115 reads (24%) | catalogued as rs141260125; called by mutect2, varscan2
- GLI4 | c.223+147C>T | Intron (SNP) | VAF 34/127 reads (27%) | catalogued as rs1338981669; called by muse, mutect2, varscan2
- GRIA4 | c.*828G>A | 3'UTR (SNP) | VAF 18/214 reads (8%) | called by muse, mutect2
- GRK7 | c.*841A>T | 3'UTR (SNP) | VAF 30/86 reads (35%) | called by muse, mutect2, varscan2
- H2BC9 | c.*130C>A | 3'UTR (SNP) | VAF 33/92 reads (36%) | catalogued as rs1385690601; called by muse, mutect2, varscan2
- HCRTR2 | c.-89C>T | 5'UTR (SNP) | VAF 48/82 reads (59%) | called by muse, mutect2, varscan2
- HS6ST2 | c.*206T>C | 3'UTR (SNP) | VAF 71/74 reads (96%) | called by muse, mutect2, varscan2
- IDH3B | c.532-38T>C | Intron (SNP) | VAF 85/182 reads (47%) | called by muse, mutect2, varscan2
- IL1RAP | c.64+102A>G | Intron (SNP) | VAF 16/78 reads (21%) | called by muse, varscan2
- IL31 | c.*262C>T | 3'UTR (SNP) | VAF 12/33 reads (36%) | called by muse, mutect2, varscan2
- INPP5B | c.*968A>G | 3'UTR (SNP) | VAF 9/37 reads (24%) | called by muse, mutect2, varscan2
- KNG1 | c.*1295C>T | 3'UTR (SNP) | VAF 18/47 reads (38%) | called by muse, mutect2, varscan2
- KPNB1 | c.2354-22A>G | Intron (SNP) | VAF 11/28 reads (39%) | called by muse, mutect2, varscan2
- LPXN | c.-51C>T | 5'UTR (SNP) | VAF 229/494 reads (46%) | called by muse, mutect2, varscan2
- LTB | c.162+32T>C | Intron (SNP) | VAF 30/70 reads (43%) | catalogued as rs745496226; called by muse, mutect2, varscan2
- LY6G5C | c.346-1100T>C | Intron (SNP) | VAF 24/48 reads (50%) | called by muse, mutect2, varscan2
- MEP1A | c.*303T>C | 3'UTR (SNP) | VAF 9/77 reads (12%) | catalogued as COSV57922100; called by muse, mutect2, varscan2
- METAP1 | chr4:98995710 G>A | 5'Flank (SNP) | VAF 14/28 reads (50%) | catalogued as rs775583097; called by muse, mutect2, varscan2
- NDEL1 | c.*470C>G | 3'UTR (SNP) | VAF 14/111 reads (13%) | called by muse, mutect2, varscan2
- NFE2L3 | c.*6A>G | 3'UTR (SNP) | VAF 53/246 reads (22%) | called by muse, mutect2, varscan2
- NFKB1 | c.*197G>A | 3'UTR (SNP) | VAF 35/83 reads (42%) | called by muse, mutect2, varscan2
- NLGN4Y | chrY:14844598 G>A | 3'Flank (SNP) | VAF 8/30 reads (27%) | called by muse, varscan2
- NLGN4Y | chrY:14844701 G>C | 3'Flank (SNP) | VAF 5/33 reads (15%) | called by muse, mutect2, varscan2
- NLGN4Y | chrY:14844844 G>C | 3'Flank (SNP) | VAF 6/36 reads (17%) | called by muse, varscan2
- NOS1 | c.*3176C>A | 3'UTR (SNP) | VAF 13/41 reads (32%) | called by muse, mutect2, varscan2
- NOX5 | c.*2109C>G | 3'UTR (SNP) | VAF 42/157 reads (27%) | called by muse, mutect2, varscan2
- NR6A1 | c.143-41212G>A | Intron (SNP) | VAF 23/579 reads (4%) | called by muse, mutect2
- PAX5 | c.*3712C>G | 3'UTR (SNP) | VAF 47/124 reads (38%) | called by muse, mutect2, varscan2
- PAX6 | c.1184-34T>A | Intron (SNP) | VAF 100/190 reads (53%) | called by muse, mutect2, varscan2
- PDE8B | c.*497_*498del | 3'UTR (DEL) | VAF 4/38 reads (11%) | catalogued as rs1491073190; called by pindel, varscan2
- PDGFB | c.-692C>T | 5'UTR (SNP) | VAF 23/51 reads (45%) | called by muse, mutect2, varscan2
- PILRB | c.-217-93C>T | Intron (SNP) | VAF 6/58 reads (10%) | catalogued as COSV60336052; called by muse, mutect2, varscan2
- PKD1L1 | c.7174-161T>C | Intron (SNP) | VAF 90/214 reads (42%) | called by muse, mutect2, varscan2
- PRMT2 | c.960+76C>G | Intron (SNP) | VAF 13/219 reads (6%) | called by muse, mutect2
- PROS2P | n.1184G>T | RNA (SNP) | VAF 24/103 reads (23%) | called by muse, mutect2, varscan2
- RBM3 | c.-111T>G | 5'UTR (SNP) | VAF 127/142 reads (89%) | called by muse, varscan2
- ROCK1P1 | n.1576T>G | RNA (SNP) | VAF 111/188 reads (59%) | called by muse, mutect2, varscan2
- RYBP | c.*611G>A | 3'UTR (SNP) | VAF 26/87 reads (30%) | called by muse, mutect2, varscan2
- SATB1 | c.*2280G>A | 3'UTR (SNP) | VAF 22/74 reads (30%) | called by muse, mutect2, varscan2
- SCN5A | c.*5C>T | 3'UTR (SNP) | VAF 12/35 reads (34%) | catalogued as rs762103625; called by muse, mutect2, varscan2
- SERTAD4 | c.*2768A>T | 3'UTR (SNP) | VAF 105/117 reads (90%) | called by muse, mutect2, varscan2
- SLC12A5 | c.122-5651C>T | Intron (SNP) | VAF 21/58 reads (36%) | called by muse, mutect2, varscan2
- SLC39A10 | c.*1590C>A | 3'UTR (SNP) | VAF 8/98 reads (8%) | called by muse, mutect2
- SPAG4 | c.717+51T>C | Intron (SNP) | VAF 3/11 reads (27%) | called by muse, mutect2
- SPATA8 | n.360A>T | RNA (SNP) | VAF 51/112 reads (46%) | called by muse, mutect2, varscan2
- SRRM4 | c.*1976G>T | 3'UTR (SNP) | VAF 23/49 reads (47%) | called by muse, mutect2, varscan2
- STBD1 | c.*829C>G | 3'UTR (SNP) | VAF 18/60 reads (30%) | called by muse, mutect2, varscan2
- TCF7 | c.1027-168G>A | Intron (SNP) | VAF 42/132 reads (32%) | called by muse, mutect2, varscan2
- TEAD1 | c.*5097T>C | 3'UTR (SNP) | VAF 23/148 reads (16%) | called by muse, mutect2, varscan2
- THEM6 | c.*644_*646del | 3'UTR (DEL) | VAF 5/58 reads (9%) | catalogued as rs1233280862; called by mutect2, pindel
- TNIK | c.*1119C>A | 3'UTR (SNP) | VAF 26/110 reads (24%) | called by muse, mutect2, varscan2
- TNXB | c.11347+302G>A | Intron (SNP) | VAF 31/124 reads (25%) | catalogued as rs1229422949; called by muse, mutect2, varscan2
- UBE2J1 | c.*1773A>G | 3'UTR (SNP) | VAF 7/57 reads (12%) | called by muse, mutect2, varscan2
- UGT2B28 | c.*194G>C | 3'UTR (SNP) | VAF 53/126 reads (42%) | catalogued as COSV100158550; called by muse, mutect2, varscan2
- WDR26 | c.*4452G>C | 3'UTR (SNP) | VAF 100/134 reads (75%) | called by muse, mutect2, varscan2
- WDR36 | c.1884+272A>T | Intron (SNP) | VAF 28/74 reads (38%) | called by muse, mutect2, varscan2
- YIF1B | c.789+500C>T | Intron (SNP) | VAF 9/74 reads (12%) | catalogued as rs780370995; called by muse, mutect2, varscan2
- YTHDC1 | c.*1250T>G | 3'UTR (SNP) | VAF 17/41 reads (41%) | called by muse, mutect2, varscan2
- ZC3H13 | c.*66T>C | 3'UTR (SNP) | VAF 27/48 reads (56%) | called by muse, mutect2, varscan2
- ZFAND2A | chr7:1152197 A>T | 3'Flank (SNP) | VAF 23/128 reads (18%) | called by muse, mutect2, varscan2
